Somatic mutation profile of tumor specimen MP2PRT-PAVUKM-TMP1-A (aliquot MP2PRT-PAVUKM-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVUKM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,211 days).
Specimen MP2PRT-PAVUKM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30acaa20-b307-419c-9a13-14e8d594d426.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUKM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUKM-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7f8f183-fd81-4a6b-9e54-65cb123db64d

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 31/346 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 32/388 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2
- CFAP74 | c.2706C>A p.N902K | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV72210586; called by muse, mutect2
- COL7A1 | c.7739G>A p.R2580H | Missense Mutation (SNP) | VAF 52/588 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1348989620; called by muse, mutect2
- GNB1 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1231842600, COSV101060718, COSV66101380; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- NRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV65731978; called by muse, mutect2
- CT47B1 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- EPPK1 | c.6238T>A p.W2080R | Missense Mutation (SNP) | VAF 50/634 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- FAT1 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 188/425 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGHV3-64 | c.350_351del p.A117Efs*? | Frame Shift Del (DEL) | VAF 35/136 reads (26%) | called by mutect2, pindel*
- MAGEE1 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PPME1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC37A2 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ZNF705G | c.99A>T p.R33S | Missense Mutation (SNP) | VAF 23/665 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- HTR1D | c.660C>A p.I220= | Silent (SNP) | VAF 40/464 reads (9%) | called by muse, mutect2
- KCNC3 | c.1752G>A p.P584= | Silent (SNP) | VAF 66/388 reads (17%) | catalogued as rs1001882554; ClinVar: benign; called by muse, mutect2, varscan2
- SERPINB5 | c.78C>A p.G26= | Silent (SNP) | VAF 148/395 reads (37%) | catalogued as rs1269094382; called by muse, mutect2, varscan2
